Somatic mutation profile of tumor specimen TCGA-IZ-8195-01A (aliquot TCGA-IZ-8195-01A-31D-2396-08) from TCGA case TCGA-IZ-8195, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 82.0 years (29,963 days).
Specimen TCGA-IZ-8195-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 529ecee4-7f03-4135-9d45-a35ab94e2014.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IZ-8195-10A (Blood Derived Normal), aliquot TCGA-IZ-8195-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3487e915-181f-484a-8911-c98d79286e2b

The open-access MAF lists 74 somatic variants for this specimen: 54 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 19, Frame Shift Del 6, Nonsense Mutation 4, Frame Shift Ins 2, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABR | c.1843A>G p.M615V (on ENST00000302538 / NM_021962.5; = p.M578V on NM_001092.5) | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV52151822; called by muse, mutect2, varscan2
- AFF1 | c.1426G>T p.D476Y | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57124054; called by muse, mutect2, varscan2
- AHI1 | c.3205G>T p.E1069* | Nonsense Mutation (SNP) | VAF 13/27 reads (48%) | catalogued as COSV55636138; called by muse, mutect2, varscan2
- ASAP2 | c.2287T>C p.Y763H | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); catalogued as COSV55638697; called by muse, mutect2
- BHMT | c.1129A>G p.K377E | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.078); catalogued as COSV57155789; called by muse, mutect2, varscan2
- CELSR3 | c.5507T>G p.L1836R | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV51151122; called by muse, mutect2, varscan2
- CFAP77 | c.919G>A p.V307M | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as rs764418663, COSV58011193; called by muse, mutect2, varscan2
- COL6A6 | c.3110T>A p.V1037E | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV62037488; called by muse, mutect2, varscan2
- DCHS1 | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV55035851; called by muse, mutect2, varscan2
- FARP1 | c.670A>C p.M224L | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.026); catalogued as COSV60348051; called by muse, mutect2, varscan2
- FAT1 | c.8624T>C p.L2875P | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71676027; called by muse, mutect2, varscan2
- GCSAML | c.346T>C p.S116P | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.469); catalogued as COSV63579566; called by muse, mutect2, varscan2
- GPT | c.1419_1420insA p.L474Ifs*73 | Frame Shift Ins (INS) | VAF 32/110 reads (29%) | catalogued as COSV52953260; called by mutect2, pindel, varscan2
- GTPBP4 | c.1676C>A p.A559D | Missense Mutation (SNP) | VAF 54/157 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.017); catalogued as COSV52987470, COSV52989155; called by muse, mutect2, varscan2
- HOXA3 | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs1336528766, COSV57828937; called by muse, mutect2, varscan2
- IFNL1 | c.217T>G p.F73V | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV61318336; called by muse, mutect2, varscan2
- IPO5 | c.1063G>A p.V355I | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.67); PolyPhen benign (0.013); catalogued as rs775571594, COSV55159885; called by muse, mutect2, varscan2
- KIAA1614 | c.314C>T p.S105F | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs767268408, COSV62553822; called by muse, mutect2, varscan2
- KIN | c.38C>G p.A13G | Missense Mutation (SNP) | VAF 61/132 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.097); catalogued as COSV59622963; called by muse, mutect2, varscan2
- KLF6 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773677946, COSV51494175, COSV99434932; called by muse, mutect2, varscan2
- LRP1 | c.5122G>A p.V1708I | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV54525786; called by muse, mutect2, varscan2
- MAML1 | c.1174G>T p.E392* | Nonsense Mutation (SNP) | VAF 24/94 reads (26%) | catalogued as COSV52988738; called by muse, mutect2, varscan2
- MTMR6 | c.1649C>G p.T550S | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV67809832; called by muse, mutect2, varscan2
- PEG3 | c.4624T>C p.C1542R | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.047); catalogued as rs530969342, COSV55647628; called by muse, mutect2, varscan2
- POLK | c.1840G>C p.E614Q | Missense Mutation (SNP) | VAF 72/159 reads (45%) | SIFT tolerated (0.55); PolyPhen benign (0.021); catalogued as COSV54039907; called by muse, mutect2, varscan2
- PPP4C | c.350G>A p.S117N | Missense Mutation (SNP) | VAF 91/152 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV54223255; called by muse, mutect2, varscan2
- REPS1 | c.1181C>G p.A394G | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV57813910; called by muse, mutect2, varscan2
- RSPH6A | c.560C>G p.A187G | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV55575509; called by muse, mutect2, varscan2
- RYR3 | c.5711T>C p.L1904P | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV66808455; called by muse, varscan2
- SAMHD1 | c.1432A>G p.K478E | Missense Mutation (SNP) | VAF 114/190 reads (60%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as COSV53432559; called by muse, mutect2, varscan2
- SEC24B | c.1409A>G p.Y470C | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1255840949, COSV54506750; called by muse, mutect2, varscan2
- SLC4A1AP | c.1018A>G p.M340V | Missense Mutation (SNP) | VAF 53/112 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV58137753; called by muse, mutect2, varscan2
- SLC6A19 | c.1399T>C p.F467L | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.019); catalogued as rs760128082, COSV58674560; called by muse, mutect2, varscan2
- SOX30 | c.978T>A p.D326E | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.858); catalogued as COSV53939651; called by muse, mutect2, varscan2
- SPATA5 | c.206A>G p.H69R | Missense Mutation (SNP) | VAF 52/112 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs201699296, COSV56784509; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TBC1D19 | c.1108T>A p.S370T | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.966); catalogued as COSV53521513; called by muse, mutect2
- TBC1D7 | c.531T>G p.F177L | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58245051; called by muse, mutect2, varscan2
- TBC1D9B | c.674A>T p.E225V | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.441); catalogued as COSV62284004; called by muse, mutect2, varscan2
- THBS1 | c.3182T>C p.L1061P | Missense Mutation (SNP) | VAF 66/171 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52955908; called by muse, mutect2, varscan2
- TMEM139 | c.340T>C p.Y114H | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60083571; called by muse, mutect2, varscan2
- TMEM245 | c.1012C>T p.R338* | Nonsense Mutation (SNP) | VAF 13/78 reads (17%) | catalogued as rs1323569302, COSV65824485; called by muse, mutect2, varscan2
- TRIM2 | c.564A>T p.E188D (on ENST00000437508; = p.E215D on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV58638697; called by muse, mutect2, varscan2
- TRIO | c.7909C>A p.R2637S | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV59990666, COSV59992421; called by muse, mutect2, varscan2
- TRMT1L | c.1717A>T p.S573C | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as COSV62273469; called by muse, mutect2, varscan2
- USP39 | c.1586T>G p.L529* | Nonsense Mutation (SNP) | VAF 41/94 reads (44%) | catalogued as COSV60383609; called by muse, mutect2, varscan2
- ASTE1 | c.851_858delinsG p.D284Gfs*19 | Frame Shift Del (DEL) | VAF 32/91 reads (35%) | called by pindel, varscan2*
- CRYBG1 | c.3909_3911del p.L1304del | In Frame Del (DEL) | VAF 41/124 reads (33%) | called by pindel, varscan2
- DMXL1 | c.4714_4721dup p.F1574Lfs*11 | Frame Shift Ins (INS) | VAF 22/58 reads (38%) | called by mutect2, varscan2
- FOXK2 | c.1394del p.P465Hfs*62 | Frame Shift Del (DEL) | VAF 18/70 reads (26%) | called by mutect2, pindel, varscan2
- GPR179 | c.3206T>G p.I1069S (on ENST00000621958; = p.I1068S on NM_001004334.4) | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- ITFG1 | c.1800del p.K600Nfs*30 | Frame Shift Del (DEL) | VAF 67/232 reads (29%) | called by mutect2, pindel, varscan2
- NCDN | c.682_692delinsC p.D228Qfs*43 | Frame Shift Del (DEL) | VAF 33/82 reads (40%) | called by pindel, varscan2*
- OR2M2 | c.990del p.S331Pfs*10 | Frame Shift Del (DEL) | VAF 44/165 reads (27%) | called by mutect2, pindel, varscan2
- ZNF292 | c.488del p.N163Tfs*18 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | called by mutect2, pindel, varscan2
- ABCA13 | c.10848C>A p.A3616= | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as COSV71294338; called by muse, mutect2, varscan2
- ACTC1 | c.165C>T p.Y55= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as rs149432225; ClinVar: likely benign; called by muse, mutect2, varscan2
- CA8 | c.192G>A p.S64= | Silent (SNP) | VAF 63/99 reads (64%) | catalogued as COSV58771292; called by muse, mutect2, varscan2
- CTNS | c.132C>T p.L44= | Silent (SNP) | VAF 13/91 reads (14%) | catalogued as rs756058217, COSV50444275; called by muse, mutect2, varscan2
- GPR75 | c.1287T>C p.S429= | Silent (SNP) | VAF 47/183 reads (26%) | catalogued as COSV61832359; called by muse, mutect2, varscan2
- HECTD4 | c.6213C>T p.P2071= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs1202014384, COSV66399855; called by muse, mutect2, varscan2
- HMG20A | c.309C>A p.P103= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as rs749576606, COSV60314240; called by muse, mutect2, varscan2
- LRPAP1 | c.744T>C p.T248= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV56347588; called by muse, mutect2, varscan2
- MBD5 | c.4140A>C p.P1380= | Silent (SNP) | VAF 49/106 reads (46%) | catalogued as COSV68698942; called by muse, mutect2, varscan2
- MLST8 | c.813C>T p.G271= | Silent (SNP) | VAF 46/190 reads (24%) | catalogued as rs1397498410, COSV57031233; called by muse, mutect2, varscan2
- MSH3 | c.1731G>A p.K577= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as COSV54151657; called by muse, mutect2, varscan2
- MYO7A | c.4017C>T p.N1339= | Silent (SNP) | VAF 33/73 reads (45%) | catalogued as rs767000906, COSV68687038; called by muse, mutect2, varscan2
- NHP2 | c.87C>A p.V29= | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as COSV51071392; called by muse, mutect2, varscan2
- OGA | c.1011T>C p.N337= | Silent (SNP) | VAF 9/117 reads (8%) | catalogued as COSV63383339; called by muse, mutect2
- PAX3 | c.1410G>A p.Q470= | Silent (SNP) | VAF 7/80 reads (9%) | catalogued as COSV100398887, COSV60592558; called by muse, mutect2
- PRDM10 | c.375C>T p.T125= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as COSV58805282; called by muse, mutect2, varscan2
- PRR19 | c.945C>T p.P315= | Silent (SNP) | VAF 73/196 reads (37%) | catalogued as COSV56627788; called by muse, mutect2, varscan2
- RSC1A1 | c.1285T>C p.L429= | Silent (SNP) | VAF 31/71 reads (44%) | catalogued as COSV60781470; called by muse, mutect2, varscan2
- SNAPC4 | c.3252G>C p.G1084= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV53737735; called by muse, mutect2
- DCHS2 | n.4233A>G | RNA (SNP) | VAF 23/47 reads (49%) | catalogued as COSV61779564; called by muse, mutect2, varscan2
